Somatic mutation profile of tumor specimen TCGA-BR-6706-01A (aliquot TCGA-BR-6706-01A-11D-1882-08) from TCGA case TCGA-BR-6706, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.1 years (23,053 days).
Specimen TCGA-BR-6706-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96a39a49-93db-4553-9616-ea2fd629643a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6706-10A (Blood Derived Normal), aliquot TCGA-BR-6706-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/379dc3d9-d251-4e65-9dfe-350ab7e95a66

The open-access MAF lists 200 somatic variants for this specimen: 160 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 38, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Splice Region 1, Intron 1, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 19/189 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EVC2 | c.2620C>T p.R874* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as rs760382778, CM092415, COSV60387825; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 17/138 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1492A>C p.S498R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs369450505; called by mutect2, varscan2
- ABCA6 | c.3457A>G p.S1153G | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV52644094; called by muse, mutect2
- ABI3BP | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV52549565; called by muse, mutect2
- ADA2 | c.412T>G p.F138V | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV52833529; called by muse, mutect2
- ADAMTS5 | c.2723A>C p.K908T | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV53184499; called by muse, mutect2
- ADGRV1 | c.7640T>G p.L2547R | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67994201; called by muse, mutect2
- AGR3 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs774697965, COSV60039297; called by muse, mutect2, varscan2
- ARHGAP19 | c.787T>G p.S263A | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57395654; called by muse, mutect2, varscan2
- ARHGAP4 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as rs996546347, COSV61686891; called by muse, mutect2
- ARHGEF26 | c.1142A>G p.Q381R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62851391; called by muse, mutect2, varscan2
- ATP1A3 | c.2144T>C p.V715A (on ENST00000545399 / NM_001256214.2; = p.V702A on NM_152296.5) | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57490868; called by muse, mutect2, varscan2
- BLK | c.1451A>G p.E484G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52055842; called by muse, mutect2, varscan2
- CACNA2D2 | c.1334A>T p.N445I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56568528; called by muse, mutect2, varscan2
- CASS4 | c.1475A>T p.E492V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV64388237; called by muse, mutect2, varscan2
- CCDC39 | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.493); catalogued as COSV56483568, COSV56492596; called by muse, mutect2, varscan2
- CCDC39 | c.637T>G p.F213V | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); catalogued as COSV56492615; called by muse, mutect2, varscan2
- CCDC93 | c.1451A>G p.K484R | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV60123940; called by muse, mutect2
- CDH26 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 56/571 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV54853781; called by muse, mutect2, varscan2
- CNTNAP2 | c.3014T>G p.V1005G | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV62247261; called by muse, mutect2
- CPN1 | c.1313A>C p.K438T | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV64942743; called by muse, mutect2
- CSRNP3 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs141222366; called by muse, mutect2, varscan2
- CYP4F2 | c.1481A>C p.D494A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs780277810, COSV55621170; called by muse, mutect2, varscan2
- DAO | c.940T>C p.Y314H | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.944); catalogued as COSV57324322; called by muse, mutect2
- DCLK2 | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV56211046; called by muse, mutect2
- DDIT4L | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1445763095, COSV56767887; called by muse, mutect2
- DDX4 | c.1322A>C p.K441T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV61756978; called by muse, mutect2
- DEFB132 | c.5A>G p.K2R | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV101212593; called by muse, mutect2, varscan2
- DEFB134 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV66363262, COSV66363298; called by muse, mutect2
- DNAI3 | c.659A>C p.N220T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54005599; called by muse, mutect2, varscan2
- DNAJA4 | c.520A>G p.I174V (on ENST00000343789; = p.I203V on NM_018602.3) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV59427057; called by muse, mutect2, varscan2
- DOP1A | c.3113A>C p.N1038T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV52717023; called by muse, mutect2
- DPP10 | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV69780089; called by muse, mutect2, varscan2
- EDAR | c.1114A>C p.K372Q | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51507268; called by muse, mutect2
- EFCAB6 | c.1958A>T p.K653I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53071441; called by muse, mutect2, varscan2
- EOMES | c.1586A>C p.N529T | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV55415169; called by muse, mutect2
- ETV5 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276673113, COSV100111883; called by muse, mutect2, varscan2
- FAT4 | c.9157T>G p.L3053V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58705539; called by muse, mutect2, varscan2
- FCRL3 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as COSV63844600; called by muse, mutect2
- FER1L6 | c.3911A>G p.K1304R | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67552523; called by muse, mutect2, varscan2
- FKBP9 | c.474T>G p.S158R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV54234159; called by muse, mutect2, varscan2
- FOXE1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as COSV64300510; called by muse, mutect2
- GCG | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64962151; called by muse, mutect2, varscan2
- GHR | c.1265A>G p.D422G | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV50128067; called by muse, mutect2, varscan2
- GNAZ | c.30A>C p.K10N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV50741184; called by muse, mutect2
- GPR176 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54448095; called by muse, mutect2, varscan2
- GPR83 | c.740T>A p.L247H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54720461; called by muse, mutect2, varscan2
- GPR87 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778550664, COSV53464340; called by muse, mutect2, varscan2
- GSDMC | c.1225T>G p.F409V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52698715; called by muse, mutect2, varscan2
- GUCY1A1 | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56655878; called by muse, mutect2, varscan2
- IL1R2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs148522700, COSV60207748; called by muse, mutect2
- IP6K3 | c.122A>G p.K41R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV53391634; called by muse, mutect2, varscan2
- IQUB | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61242404; called by muse, mutect2, varscan2
- ISYNA1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs138096546; called by muse, mutect2, varscan2
- JAK3 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767428670, COSV71685857; called by mutect2, varscan2
- KIR2DL1 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV52414969; called by muse, mutect2, varscan2
- LPCAT2 | c.1403T>G p.V468G | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV50899269; called by muse, mutect2
- LRP1B | c.4520A>C p.Q1507P | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67268466, COSV67278133; called by muse, mutect2
- LRP4 | c.3982C>T p.P1328S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.45); catalogued as COSV66138470; called by muse, mutect2, varscan2
- LRRK2 | c.5337A>C p.Q1779H | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV54168501; called by muse, mutect2
- LRTM1 | c.385T>G p.L129V | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.286); catalogued as COSV55576409; called by muse, mutect2
- LTB4R | c.296T>A p.V99D | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51867948; called by muse, mutect2
- MAOB | c.350A>C p.N117T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65206712; called by muse, mutect2, varscan2
- MCM4 | c.1800G>A p.K600= | Splice Region (SNP) | VAF 14/105 reads (13%) | catalogued as COSV50631618; called by muse, mutect2, varscan2
- MGAT5 | c.2093A>C p.K698T | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV56100538; called by muse, mutect2
- MRPS15 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as rs781603240, COSV58971304; called by mutect2, varscan2
- MS4A10 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57633759; called by muse, mutect2, varscan2
- MS4A6A | c.50A>C p.N17T | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV60621585; called by muse, mutect2, varscan2
- MTSS2 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369371548, COSV58699794; called by muse, mutect2
- MTUS1 | c.3502-2A>C p.X1168_splice (on ENST00000262102 / NM_001363061.1; = p.X334_splice on NM_020749.4) | Splice Site (SNP) | VAF 7/96 reads (7%) | catalogued as COSV50583033; called by muse, mutect2
- MUC16 | c.37636T>G p.F12546V | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV67489668; called by muse, mutect2
- MUC17 | c.756A>C p.Q252H | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60301324; called by muse, mutect2
- MYOT | c.1397T>A p.L466H | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51801141; called by muse, mutect2, varscan2
- NALCN | c.899T>C p.F300S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV51961748; called by muse, mutect2, varscan2
- NAPB | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as rs749882482, COSV65465174; called by muse, mutect2, varscan2
- NDST4 | c.245T>A p.L82H | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52134932; called by muse, mutect2, varscan2
- NDUFAF1 | c.933A>C p.E311D | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52976295; called by muse, mutect2
- NETO2 | c.1214A>G p.D405G | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.516); catalogued as COSV57455348; called by muse, mutect2
- NGF | c.497A>C p.N166T | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV65688796; called by muse, mutect2, varscan2
- NLRP9 | c.1701A>C p.E567D | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as COSV60467271; called by muse, mutect2, varscan2
- NOLC1 | c.990T>G p.D330E | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV64181036; called by muse, mutect2, varscan2
- NUMA1 | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as rs1342065233, COSV61186157; called by muse, mutect2, varscan2
- OR2L8 | c.922T>C p.C308R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV61728167; called by muse, mutect2, varscan2
- OR4C6 | c.747T>A p.F249L | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV100051268; called by muse, mutect2
- OR5D14 | c.538T>C p.F180L | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as COSV59458259; called by muse, mutect2, varscan2
- OR7G1 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV53316950, COSV53318851; called by muse, mutect2
- PAM | c.1055A>G p.K352R | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV57219154; called by muse, mutect2
- PARP4 | c.1791T>G p.D597E | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as COSV67963955; called by muse, mutect2, varscan2
- PCDHAC2 | c.1268T>G p.V423G | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV53866543; called by muse, mutect2
- PER3 | c.1996T>C p.S666P | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV62707633; called by muse, mutect2
- PIK3C3 | c.2605G>C p.A869P | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56283829; called by muse, mutect2
- PKDREJ | c.3871G>A p.G1291R | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53552644; called by muse, mutect2
- PLPPR1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs200667385; called by muse, mutect2, varscan2
- POGZ | c.1688A>C p.K563T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55041423; called by muse, mutect2, varscan2
- POLD1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs746649739, COSV70957053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARGC1A | c.1999A>G p.R667G | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV53532943; called by muse, mutect2
- PRAMEF1 | c.968A>C p.K323T | Missense Mutation (SNP) | VAF 50/500 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100179302; called by muse, varscan2
- PREX1 | c.2600G>T p.C867F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV64256258; called by muse, mutect2, varscan2
- RALGAPA1 | c.4858A>G p.S1620G | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV99352649; called by muse, mutect2, varscan2
- RAX | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV56875372; called by muse, mutect2
- RBM46 | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55981556; called by muse, mutect2
- REPS2 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV58187527; called by muse, mutect2, varscan2
- RMC1 | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52574191; called by muse, mutect2
- RTTN | c.6197G>A p.G2066E | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV55351151; called by muse, mutect2
- SALL4 | c.2396A>G p.K799R | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV53855586; called by muse, mutect2
- SH2D2A | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV63885425; called by muse, mutect2, varscan2
- SH3TC2 | c.3257T>C p.L1086P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60467388; called by muse, mutect2
- SHPRH | c.3029A>C p.K1010T (on ENST00000275233 / NM_001042683.3; = p.K1019T on NM_173082.3) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51616627; called by muse, mutect2
- SLC18A2 | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV53693304; called by muse, mutect2, varscan2
- SLC1A6 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.375); catalogued as rs149934975; called by muse, mutect2, varscan2
- SLC45A2 | c.459T>G p.D153E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56875174; called by muse, mutect2, varscan2
- SMARCA2 | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1301145280, COSV61809252; called by muse, mutect2
- SPINT2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs749590138, COSV56648985; called by muse, mutect2, varscan2
- SSTR4 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54799969; called by muse, mutect2, varscan2
- STAB2 | c.6439G>A p.G2147S | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV66345911; called by muse, mutect2, varscan2
- SYNE3 | c.1461G>C p.M487I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62082270; called by muse, mutect2, varscan2
- TACC2 | c.1466T>C p.V489A | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV57770979; called by muse, mutect2, varscan2
- TAF9B | c.658_660del p.L220del | In Frame Del (DEL) | VAF 21/161 reads (13%) | catalogued as rs782438211; called by mutect2, pindel, varscan2
- TCHH | c.5102G>A p.R1701H | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV64277449; called by muse, mutect2
- TDO2 | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV72233095; called by muse, mutect2, varscan2
- TG | c.2099A>G p.N700S | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV55092156; called by muse, mutect2, varscan2
- TIAM1 | c.939A>C p.Q313H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV54571911; called by muse, mutect2, varscan2
- TLR4 | c.1492T>G p.L498V (on ENST00000355622 / NM_138554.5; = p.L458V on NM_003266.4) | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923526; called by muse, mutect2
- TMEM117 | c.1462T>G p.L488V | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.259); catalogued as COSV56916890; called by muse, mutect2, varscan2
- TRMT1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52835785; called by muse, mutect2
- TRPC5 | c.2226T>G p.N742K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53301788; called by muse, mutect2, varscan2
- TSPAN12 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56081676; called by muse, mutect2
- TTN | c.61865T>G p.L20622R (on ENST00000591111; = p.L13198R on NM_003319.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV60304497; called by muse, mutect2, varscan2
- TTN | c.58858G>A p.V19620I (on ENST00000591111; = p.V12196I on NM_003319.4) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | PolyPhen probably damaging (0.99); catalogued as COSV60304523; called by muse, mutect2
- UBA7 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV61093453; called by muse, mutect2
- UBE3B | c.2327A>G p.E776G | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55097880; called by muse, mutect2, varscan2
- UBR2 | c.2237A>C p.N746T | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV65752272; called by muse, mutect2, varscan2
- UGT3A1 | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57102451; called by muse, mutect2
- UNC79 | c.1490A>G p.Q497R (on ENST00000393151 / NM_001346218.2; = p.Q320R on NM_020818.5) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.969); catalogued as COSV56407524; called by muse, mutect2
- USP26 | c.1616T>G p.V539G | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63709641; called by muse, mutect2
- USP28 | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770592432, COSV50186010; called by muse, mutect2, varscan2
- WWC1 | c.489A>C p.E163D | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV54657739; called by muse, mutect2
- WWC3 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV66506922; called by muse, mutect2, varscan2
- XRN1 | c.4342C>T p.R1448* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53810034; called by muse, mutect2, varscan2
- ZFHX4 | c.4960A>G p.S1654G | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.117); catalogued as COSV51492586, COSV99261788; called by muse, mutect2
- ZFP69B | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64315993; called by muse, mutect2
- ZFPM2 | c.1132T>G p.L378V | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV65875595; called by muse, mutect2
- ZFR | c.1661T>C p.L554P | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.986); catalogued as COSV54057303; called by muse, mutect2, varscan2
- ZNF347 | c.297A>T p.K99N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV61970684; called by mutect2, varscan2
- ZNF462 | c.6737T>C p.V2246A | Missense Mutation (SNP) | VAF 51/430 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.028); catalogued as COSV52949810; called by muse, mutect2, varscan2
- ZNF521 | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV64131290; called by muse, mutect2
- ZNF559 | c.917T>G p.F306C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57837134; called by muse, mutect2, varscan2
- ZNF610 | c.279A>C p.K93N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.39); catalogued as COSV58346348; called by muse, mutect2, varscan2
- ZNF630 | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV52098008; called by muse, mutect2, varscan2
- ZNF789 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV58875123; called by muse, mutect2, varscan2
- ZNRF3 | c.1127A>T p.N376I (on ENST00000544604 / NM_001206998.2; = p.N276I on NM_032173.3) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); catalogued as COSV60437968; called by muse, mutect2, varscan2
- ZP4 | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63913330; called by muse, mutect2
- ANXA8 | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2
- CDK12 | c.828dup p.P277Sfs*21 | Frame Shift Ins (INS) | VAF 20/145 reads (14%) | called by mutect2, pindel, varscan2
- PTPRT | c.3218del p.N1073Tfs*8 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | called by mutect2, pindel, varscan2
- TPD52L2 | c.273_274del p.N92Pfs*7 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- TRAV40 | c.248A>T p.K83I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2
- ANK2 | c.8883T>C p.S2961= | Silent (SNP) | VAF 27/231 reads (12%) | catalogued as COSV52184848; called by muse, mutect2, varscan2
- ARHGEF6 | c.564C>T p.Y188= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs1458824176, COSV51688508, COSV51693828; called by muse, mutect2, varscan2
- CCDC110 | c.2028T>C p.F676= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV56873109; called by muse, mutect2
- COL1A2 | c.1377C>T p.I459= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs770230919, COSV51957882, COSV51965060; ClinVar: likely benign; called by mutect2, varscan2
- CTTNBP2 | c.1179T>C p.D393= | Silent (SNP) | VAF 54/281 reads (19%) | catalogued as COSV50465175; called by muse, mutect2, varscan2
- CTU2 | c.588G>A p.P196= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs766730727, COSV56335284; called by mutect2, varscan2
- DCC | c.1578A>G p.Q526= | Silent (SNP) | VAF 25/244 reads (10%) | catalogued as COSV59130966; called by muse, mutect2, varscan2
- DICER1 | c.3618G>A p.K1206= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as COSV100601591; called by muse, mutect2
- DLGAP3 | c.1092T>C p.T364= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV52397114; called by muse, mutect2, varscan2
- DRD5 | c.1179C>T p.L393= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1358208240, COSV58580132; called by muse, mutect2
- ESYT1 | c.834C>T p.T278= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV57276009; called by muse, mutect2, varscan2
- FAT2 | c.10011T>C p.G3337= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV55828227; called by mutect2, varscan2
- FNIP2 | c.2661T>C p.I887= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV52445063; called by muse, mutect2, varscan2
- FOXQ1 | c.657C>T p.R219= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1186510314, COSV57259397; called by muse, mutect2
- FSCB | c.945A>G p.K315= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV61218952, COSV61219385; called by muse, mutect2
- GPATCH2 | c.594C>T p.A198= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV65128461; called by muse, mutect2
- HTR1F | c.805A>C p.R269= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV60391049; called by muse, mutect2, varscan2
- IKZF2 | c.726A>G p.E242= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV59575946, COSV59583456; called by muse, mutect2, varscan2
- KBTBD2 | c.1617A>G p.R539= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as COSV58364212; called by muse, mutect2, varscan2
- LAMA4 | c.2076T>C p.A692= (on ENST00000230538 / NM_001105206.3; = p.A685= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV57903997; called by muse, mutect2
- MGA | c.5340A>T p.T1780= (on ENST00000219905 / NM_001164273.1; = p.T1571= on NM_001080541.2) | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV54961921; called by muse, mutect2
- MUC17 | c.12069T>G p.T4023= | Silent (SNP) | VAF 18/251 reads (7%) | catalogued as COSV60301329; called by muse, mutect2
- MYF6 | c.84A>G p.A28= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV57353101; called by muse, mutect2
- NEBL | c.1089A>C p.S363= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as COSV65805434; called by muse, mutect2
- NR1H4 | c.378G>A p.A126= (on ENST00000551379 / NM_001206993.2; = p.A116= on NM_005123.4) | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as rs767379406, COSV51849366, COSV51853756; called by muse, mutect2
- OR4F6 | c.483T>C p.A161= | Silent (SNP) | VAF 41/288 reads (14%) | catalogued as COSV61027518; called by muse, mutect2, varscan2
- PGM1 | c.831G>A p.K277= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as COSV64301365; called by muse, mutect2
- PLCL1 | c.2343T>C p.T781= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV70824160, COSV70870375; called by muse, mutect2, varscan2
- PRIMPOL | c.588T>G p.A196= | Silent (SNP) | VAF 16/167 reads (10%) | catalogued as COSV59250413; called by muse, mutect2
- RBCK1 | c.960G>A p.E320= (on ENST00000356286 / NM_031229.4; = p.E278= on NM_006462.6) | Silent (SNP) | VAF 36/229 reads (16%) | catalogued as rs1465436615, COSV62293246; called by muse, mutect2, varscan2
- SERINC1 | c.136T>C p.L46= | Silent (SNP) | VAF 13/183 reads (7%) | catalogued as COSV60102804; called by muse, mutect2
- STRBP | c.315G>A p.L105= | Silent (SNP) | VAF 6/131 reads (5%) | catalogued as COSV62120035; called by muse, mutect2
- TBC1D32 | c.1992T>C p.S664= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV51552806; called by muse, mutect2
- THSD7A | c.1764C>T p.N588= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs568263650, COSV70260293, COSV70262361; called by muse, mutect2, varscan2
- TK2 | c.165T>G p.T55= (on ENST00000299697; = p.T111= on NM_004614.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV55283859; called by muse, mutect2, varscan2
- TRPM3 | c.1749T>G p.A583= (on ENST00000357533 / NM_001366142.2; = p.A416= on NM_020952.6) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV62593605; called by muse, mutect2, varscan2
- TRPM4 | c.3117C>T p.L1039= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as rs746446243, COSV53268217; called by muse, mutect2
- TTN | c.53535A>G p.P17845= (on ENST00000591111; = p.P10421= on NM_003319.4) | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV60304552; called by muse, mutect2
- ERCC6 | c.1397+7805A>C | Intron (SNP) | VAF 12/62 reads (19%) | catalogued as COSV63393865; called by muse, mutect2, varscan2
- HUNK | c.*2T>A | 3'UTR (SNP) | VAF 12/81 reads (15%) | catalogued as COSV104372802, COSV99527859; called by muse, mutect2, varscan2
